Gene-level copy-number profile of tumor specimen TCGA-23-1113-01A from TCGA case TCGA-23-1113, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 48.7 years (17,791 days).
Specimen TCGA-23-1113-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3ea8c102-7d7b-49a5-893b-a1ea2fdbe6ae.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1113-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6576a140-f5a7-46da-a49c-d7d1c1be429f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 22,526; copy number 2: 35,694; copy number 3: 1,284; copy number 4: 205; copy number 5: 89.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1113-01A-01D-0428-01): tumor purity 0.93, ploidy 1.66, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:56,900,041–57,320,020, 11 genes: AC008937.1, SETD9, MIER3, AC008937.3, AC016644.1, AC114973.1, AC034244.1, AC034244.2, Y_RNA, GPBP1, AC025470.1.
- chr11:128,965,060–129,296,481, 5 genes: ARHGAP32, RNU6-876P, Y_RNA, RNU6-874P, ZNF123P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 89 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr19:7,112,255–8,981,342, 89 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 22,526. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
